Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZG, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZG-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DOB:

Physician:

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) RULE OUT LEFT INFERIOR PARATHYROID:

Fibrous tissue, no parathyroid identified.

(B) LEFT THYROID LOBE:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT (6.0 CM) CONFINED TO THYROID.

Margins grossly free.

(C) RULE OUT RIGHT PARATHYROID:

Thyroid tissue present, no parathyroid identified.

(D) RIGHT THYROID LOBE:

Thyroid, no tumor present.

(E) RULE OUT RIGHT PARATHYROID #2:

Lymph node, no tumor present, no parathyroid identified.

(F) LEFT PARATRACHEAL DISSECTION:

Fibroadipose tissue, no tumor present, no lymph nodes identified.

ICD-O-3

Path: carcinoma, papillary, follicular variant
8340/3

CQCF: carcinoma, papillary, thyroid
8260/3

Site: Thyroid, NOS C73.9

Entire report and diagnosis completed by

lw
6/17/12

GROSS DESCRIPTION

(A) RULE OUT LEFT INFERIOR PARATHYROID - A portion of 0.2 x 0.1 x 0.1 cm tan-pink soft tissue. One touch preparation is performed. Specimen is entirely submitted for frozen section as A.

*FS/DX: FIBROUS TISSUE, NO PARATHYROID IDENTIFIED.

(B) LEFT THYROID LOBE - A lobe of thyroid (8.0 x 4.2 x 3.2 cm). There is a well-circumscribed nodule at the lower pole (6.0 x 4.0 x 3.2). The entire nodule is well-encapsulated. The nodule is tan-white with focal areas of hemorrhage. Representative section submitted to the tumor bank.

SECTION CODE: B1, non-neoplastic thyroid; B2-B8, representative sections from tumor.

(C) RULE OUT RIGHT PARATHYROID - A 0.3 cm red-tan tissue fragment. One touch preparation is made and the entire tissue is submitted for frozen section evaluation in C.

*FS/DX: THYROID TISSUE, NO PARATHYROID IDENTIFIED.

(D) RIGHT THYROID LOBE STITCH AT SUPERIOR POLE - A lobe of thyroid (4.2 x 2.5 x 1.7 cm). No definitive focal lesion identified. Entire specimen submitted in D1-D5.

(E) RULE OUT RIGHT PARATHYROID #2 - A 0.3 cm red-tan tissue fragment. A touch prep is made and the specimen is entirely submitted for frozen section evaluation in E.

*FS/DX: LYMPH NODE, NO PARATHYROID IDENTIFIED.

(F) LEFT PARATRACHEAL DISSECTION - A nonoriented irregular fragment of fibroadipose tissue (1.0 x 0.8 x 0.2 cm). The specimen is serially sectioned and no lesions or lymph nodes grossly identified. Entirely submitted in F.

Page 1 of 2

Surgical Pathology Report

File under: Pathology

[page 2 of 2]
Surgical Pathology Report

DOB:

Physician:

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, M-83403

"Some tests reported here may have been developed and performance characteristics determined by
by the U.S. Food and Drug Administration."

these tests have not been specifically cleared or approved

Released by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file 9a59628d-3eb6-4897-838a-b9702651cb45 (TCGA-EL-A3ZG.347CFFC5-0A24-486B-8254-62D8E8F77643.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).